Somatic mutation profile of tumor specimen 0DNMAQ from CCDI case PBCBJJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 17.9 years (6,556 days).
Specimen 0DNMAQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b10dac0c-a307-4156-9ad3-44141d44c387.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNMA0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e36ee50e-3bda-4f8b-ba25-9ab2a94cf5a5

The open-access MAF lists 79 somatic variants for this specimen: 55 protein-altering or splice-affecting, 12 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 12, Intron 6, 3'UTR 3, 5'UTR 3, Splice Site 2, Frame Shift Del 2, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP9 | c.4247T>A p.F1416Y | Missense Mutation (SNP) | VAF 32/1094 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.259); catalogued as COSV62348540; called by muse, mutect2
- ANKS4B | c.14A>G p.Y5C | Missense Mutation (SNP) | VAF 48/1035 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777621058; called by muse, mutect2
- COL6A6 | c.4531C>T p.P1511S | Missense Mutation (SNP) | VAF 27/862 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as COSV62020186; called by muse, mutect2
- CPZ | c.883G>A p.G295S (on ENST00000360986 / NM_001014447.3; = p.G284S on NM_003652.3) | Missense Mutation (SNP) | VAF 54/864 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778557300, COSV100248848, COSV59924724; called by muse, mutect2
- DST | c.17623C>G p.R5875G (on ENST00000361203 / NM_001374722.1; = p.R3572G on NM_015548.5) | Missense Mutation (SNP) | VAF 47/297 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55040729; called by muse, mutect2, varscan2
- GSDMC | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 50/926 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.203); catalogued as rs762673763; called by muse, mutect2
- KPRP | c.58G>T p.G20C | Missense Mutation (SNP) | VAF 382/799 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.186); catalogued as COSV64223115; called by muse, mutect2, varscan2
- MUC17 | c.10079T>A p.L3360H | Missense Mutation (SNP) | VAF 351/876 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs200579227; called by muse, mutect2, varscan2
- MYOM2 | c.837G>C p.Q279H | Missense Mutation (SNP) | VAF 36/1092 reads (3%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.866); catalogued as COSV100037994; called by muse, mutect2
- OR1J4 | c.541C>A p.L181I | Missense Mutation (SNP) | VAF 38/859 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.424); catalogued as COSV61590275; called by muse, mutect2
- RASAL3 | c.1415C>A p.A472D | Missense Mutation (SNP) | VAF 15/382 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs1172404085; called by muse, mutect2
- SERPINB13 | c.784A>T p.I262L | Missense Mutation (SNP) | VAF 48/928 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV104371721; called by muse, mutect2
- SLC9A4 | c.805C>G p.R269G | Missense Mutation (SNP) | VAF 68/1273 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.116); catalogued as rs1038745803; called by muse, mutect2
- SPATA16 | c.1205G>T p.S402I | Missense Mutation (SNP) | VAF 498/1098 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); catalogued as COSV63526625; called by muse, mutect2, varscan2
- TNFSF13B | c.526A>G p.S176G | Missense Mutation (SNP) | VAF 269/616 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV101022372; called by muse, mutect2, varscan2
- UBR5 | c.8187+5G>C | Splice Region (SNP) | VAF 355/777 reads (46%) | catalogued as COSV55282280; called by muse, mutect2, varscan2
- ZNF558 | c.196A>G p.T66A | Missense Mutation (SNP) | VAF 238/577 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0.017); catalogued as rs149091563; called by muse, mutect2, varscan2
- ADCY6 | c.416T>G p.L139R | Missense Mutation (SNP) | VAF 35/567 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- AP3D1 | c.856+2T>C p.X286_splice | Splice Site (SNP) | VAF 26/829 reads (3%) | called by muse, mutect2
- C1orf116 | c.448A>C p.T150P | Missense Mutation (SNP) | VAF 79/356 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CARD9 | c.1194G>T p.Q398H | Missense Mutation (SNP) | VAF 98/454 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CFAP94 | c.1313C>A p.T438K (on ENST00000320267 / NM_001352064.2; = p.T444K on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 134/988 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- CHD5 | c.1590+1G>A p.X530_splice | Splice Site (SNP) | VAF 16/452 reads (4%) | called by muse, mutect2
- CLCN2 | c.1568A>G p.E523G | Missense Mutation (SNP) | VAF 299/647 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CPED1 | c.1444A>T p.M482L | Missense Mutation (SNP) | VAF 32/1084 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CPED1 | c.1964A>G p.E655G | Missense Mutation (SNP) | VAF 62/1542 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.183); called by muse, mutect2
- DCLRE1A | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 463/948 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPC2 | c.169C>G p.R57G | Missense Mutation (SNP) | VAF 32/1088 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- FAT2 | c.2986A>T p.N996Y | Missense Mutation (SNP) | VAF 30/763 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FLG | c.4156G>C p.G1386R | Missense Mutation (SNP) | VAF 215/466 reads (46%) | SIFT tolerated (0.91); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- GLDN | c.1394C>A p.T465N | Missense Mutation (SNP) | VAF 117/516 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GON4L | c.6485G>A p.R2162H | Missense Mutation (SNP) | VAF 120/637 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IL18R1 | c.1442A>T p.D481V | Missense Mutation (SNP) | VAF 67/925 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- KLF14 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 28/606 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2
- KMT2D | c.4708C>A p.P1570T | Missense Mutation (SNP) | VAF 268/609 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- L2HGDH | c.1156C>A p.Q386K | Missense Mutation (SNP) | VAF 44/1171 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.679); called by muse, mutect2
- LACC1 | c.128G>A p.C43Y | Missense Mutation (SNP) | VAF 68/1354 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.017); called by muse, mutect2
- LGALS3BP | c.1475A>T p.Y492F | Missense Mutation (SNP) | VAF 225/628 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- LRIT3 | c.1686G>T p.Q562H | Missense Mutation (SNP) | VAF 41/641 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.35); called by muse, mutect2
- MAGI1 | c.3362T>C p.F1121S (on ENST00000402939 / NM_001033057.2; = p.F1150S on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 126/771 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- MATN3 | c.704G>C p.S235T | Missense Mutation (SNP) | VAF 42/1673 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2
- MUC3A | c.9189C>A p.D3063E | Missense Mutation (SNP) | VAF 64/1224 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2
- NUGGC | c.1737C>A p.D579E | Missense Mutation (SNP) | VAF 315/759 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR6C65 | c.633G>T p.L211F | Missense Mutation (SNP) | VAF 179/899 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- PEG10 | c.461T>C p.M154T (on ENST00000482108 / NM_001040152.2; = p.M188T on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/710 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2
- PIK3C2B | c.2551A>T p.S851C | Missense Mutation (SNP) | VAF 39/868 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); called by muse, mutect2
- RASGRP3 | c.1078C>G p.L360V | Missense Mutation (SNP) | VAF 16/534 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RCL1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 137/189 reads (72%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SMARCC2 | c.2746G>A p.E916K | Missense Mutation (SNP) | VAF 452/992 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- SNX15 | c.298del p.A100Qfs*29 | Frame Shift Del (DEL) | VAF 276/645 reads (43%) | called by mutect2, varscan2
- SPATA32 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 90/492 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- TNIK | c.1907C>G p.P636R | Missense Mutation (SNP) | VAF 153/863 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- TTN | c.49706G>A p.S16569N (on ENST00000591111; = p.S9145N on NM_003319.4) | Missense Mutation (SNP) | VAF 205/1025 reads (20%) | PolyPhen benign (0.031); called by muse, mutect2, varscan2
- UBR4 | c.6147del p.T2050Pfs*14 | Frame Shift Del (DEL) | VAF 141/462 reads (31%) | called by mutect2, varscan2
- XAGE5 | c.74A>G p.E25G | Missense Mutation (SNP) | VAF 208/691 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); called by muse, varscan2
- ANKRD30A | c.3408T>A p.I1136= (on ENST00000611781; = p.I1080= on NM_052997.2) | Silent (SNP) | VAF 144/891 reads (16%) | called by muse, mutect2, varscan2
- ECHDC1 | c.399C>T p.C133= (on ENST00000531967 / NM_001139510.1; = p.C127= on NM_001002030.2) | Silent (SNP) | VAF 391/673 reads (58%) | called by muse, mutect2, varscan2
- EIF4B | c.462G>T p.L154= | Silent (SNP) | VAF 36/992 reads (4%) | called by muse, mutect2
- GALNT14 | c.960G>T p.G320= | Silent (SNP) | VAF 331/762 reads (43%) | called by muse, mutect2, varscan2
- IFI44L | c.690A>T p.V230= | Silent (SNP) | VAF 64/1238 reads (5%) | called by muse, mutect2
- MDM1 | c.6G>A p.P2= | Silent (SNP) | VAF 98/520 reads (19%) | catalogued as rs1339624308; called by muse, mutect2, varscan2
- MTUS1 | c.2250C>T p.A750= | Silent (SNP) | VAF 162/954 reads (17%) | catalogued as rs776848545; called by muse, mutect2, varscan2
- OR5F1 | c.672C>A p.S224= | Silent (SNP) | VAF 286/561 reads (51%) | called by muse, mutect2, varscan2
- PKP1 | c.1242G>A p.L414= | Silent (SNP) | VAF 142/678 reads (21%) | called by muse, mutect2, varscan2
- SLC30A10 | c.1098T>A p.I366= | Silent (SNP) | VAF 47/976 reads (5%) | called by muse, mutect2
- TMEM266 | c.1389C>T p.L463= | Silent (SNP) | VAF 63/541 reads (12%) | catalogued as rs370146123; called by muse, mutect2, varscan2
- ZNF440 | c.261T>G p.V87= | Silent (SNP) | VAF 52/1234 reads (4%) | called by muse, mutect2
- ACTN4 | c.-4C>T | 5'UTR (SNP) | VAF 50/322 reads (16%) | catalogued as rs1197082470; called by muse, mutect2, varscan2
- BEST3 | c.482-5639C>G | Intron (SNP) | VAF 27/863 reads (3%) | called by muse, mutect2
- C3orf18 | c.-25C>T | 5'UTR (SNP) | VAF 14/124 reads (11%) | called by muse, mutect2, varscan2
- CCDC191 | c.1414-30G>T | Intron (SNP) | VAF 265/555 reads (48%) | called by muse, mutect2, varscan2
- GBP1 | c.*4C>A | 3'UTR (SNP) | VAF 127/719 reads (18%) | called by muse, mutect2, varscan2
- KCNK17 | c.*84A>C | 3'UTR (SNP) | VAF 125/190 reads (66%) | called by muse, mutect2, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 8/101 reads (8%) | called by muse, mutect2
- MED12L | c.2145+18T>G | Intron (SNP) | VAF 85/385 reads (22%) | called by muse, mutect2, varscan2
- NOP10 | c.-28A>T | 5'UTR (SNP) | VAF 216/455 reads (47%) | catalogued as COSV100182446; called by muse, mutect2, varscan2
- NPM1 | c.583-64G>T | Intron (SNP) | VAF 146/297 reads (49%) | called by muse, mutect2, varscan2
- SNCG | c.363+43G>T | Intron (SNP) | VAF 112/219 reads (51%) | called by muse, mutect2, varscan2
- VNN3 | c.*426G>A | 3'UTR (SNP) | VAF 183/779 reads (23%) | called by muse, mutect2, varscan2
